Somatic mutation profile of tumor specimen HCM-CSHL-0065-C20-06A (aliquot HCM-CSHL-0065-C20-06A-01D-A768-36) from HCMI case HCM-CSHL-0065-C20, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 63.3 years (23,111 days).
Specimen HCM-CSHL-0065-C20-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b0e23808-a9ae-4c80-95cc-7bd75733bfa4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0065-C20-10A (Blood Derived Normal), aliquot HCM-CSHL-0065-C20-10A-01D-A768-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b2b1f936-c929-4750-a72c-67199a17ff00

The open-access MAF lists 125 somatic variants for this specimen: 68 protein-altering or splice-affecting, 41 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 58, Silent 41, Intron 6, Frame Shift Del 3, Nonsense Mutation 3, 5'UTR 3, 3'UTR 3, Splice Region 2, 5'Flank 2, In Frame Del 1, Splice Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.731G>A p.G244D | Missense Mutation (SNP) | VAF 171/229 reads (75%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs985033810, CM056069, CM070298, COSV52661058, COSV52724858, COSV52839584; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ALPP | c.1363G>A p.A455T | Missense Mutation (SNP) | VAF 224/403 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.273); catalogued as rs763916531; called by muse, mutect2, varscan2
- APC | c.4128T>A p.Y1376* | Nonsense Mutation (SNP) | VAF 54/81 reads (67%) | catalogued as CD058149, CM106639, COSV57326134, COSV57340615, COSV57378080; called by muse, mutect2, varscan2
- CADPS2 | c.2839G>A p.A947T | Missense Mutation (SNP) | VAF 90/201 reads (45%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.993); catalogued as rs368742944, COSV57361048; called by muse, mutect2, varscan2
- CDH11 | c.1267C>T p.R423C | Missense Mutation (SNP) | VAF 120/248 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs1177559829, COSV51768028; called by muse, mutect2, varscan2
- CHGB | c.1700A>G p.N567S | Missense Mutation (SNP) | VAF 68/425 reads (16%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.462); catalogued as rs751617009; called by muse, mutect2, varscan2
- CHPF2 | c.1606C>T p.R536C | Missense Mutation (SNP) | VAF 68/364 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs764713631; called by muse, mutect2, varscan2
- CLASP1 | c.2149C>T p.R717* | Nonsense Mutation (SNP) | VAF 44/183 reads (24%) | catalogued as COSV55330955; called by muse, mutect2, varscan2
- DLG1 | c.1088G>A p.G363D | Missense Mutation (SNP) | VAF 48/177 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs866931281; called by muse, mutect2, varscan2
- FBN3 | c.2542C>T p.R848C | Missense Mutation (SNP) | VAF 66/142 reads (46%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.765); catalogued as rs571909633, COSV54457414; called by muse, mutect2, varscan2
- FGD1 | c.1699C>T p.R567* | Nonsense Mutation (SNP) | VAF 173/204 reads (85%) | catalogued as rs931466859, COSV100910777; called by muse, mutect2, varscan2
- GPRC5C | c.1021G>A p.V341I (on ENST00000652232; = p.V296I on NM_018653.4) | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT tolerated (0.58); PolyPhen benign (0.012); catalogued as rs201878519; called by muse, mutect2, varscan2
- GRIN2A | c.4223C>T p.T1408M | Missense Mutation (SNP) | VAF 121/471 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs763219483, COSV58061178; called by muse, mutect2, varscan2
- KCNH7 | c.275G>A p.R92K | Missense Mutation (SNP) | VAF 60/211 reads (28%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.887); catalogued as COSV59807697; called by muse, mutect2, varscan2
- KCNN1 | c.1075G>A p.A359T | Missense Mutation (SNP) | VAF 62/307 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.746); catalogued as rs1202217199, COSV55841356; called by muse, mutect2, varscan2
- KIR2DL3 | c.253T>A p.F85I | Missense Mutation (SNP) | VAF 171/788 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.811); catalogued as rs779850872; called by muse, mutect2, varscan2
- KLC1 | c.885G>A p.A295= | Splice Region (SNP) | VAF 98/154 reads (64%) | catalogued as rs943212490, COSV99871737; called by muse, mutect2, varscan2
- LPAR4 | c.876G>T p.M292I | Missense Mutation (SNP) | VAF 143/158 reads (91%) | SIFT tolerated (0.95); PolyPhen benign (0.013); catalogued as COSV70912459; called by muse, mutect2, varscan2
- LRP1B | c.9319G>A p.E3107K | Missense Mutation (SNP) | VAF 42/179 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.045); catalogued as COSV101262056; called by muse, mutect2, varscan2
- NTRK3 | c.1822G>A p.G608S | Missense Mutation (SNP) | VAF 87/256 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.031); catalogued as rs760692815, COSV62295252, COSV62297183; called by muse, mutect2, varscan2
- NWD2 | c.2494C>T p.R832W | Missense Mutation (SNP) | VAF 88/179 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58749949; called by muse, mutect2, varscan2
- PCDH17 | c.1589C>T p.T530M | Missense Mutation (SNP) | VAF 108/610 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as rs1180162744, COSV64975946; called by muse, mutect2, varscan2
- PCDHA3 | c.1915G>A p.E639K | Missense Mutation (SNP) | VAF 96/313 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.783); catalogued as COSV100793854; called by muse, mutect2, varscan2
- PLCG1 | c.1466C>A p.S489Y | Missense Mutation (SNP) | VAF 49/434 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as COSV54821616; called by muse, mutect2, varscan2
- PSMD3 | c.622G>A p.A208T | Missense Mutation (SNP) | VAF 106/259 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs752964262, COSV52856469; called by muse, mutect2, varscan2
- PTCHD3 | c.830C>T p.T277M | Missense Mutation (SNP) | VAF 96/381 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.56); catalogued as rs147881350; called by muse, mutect2, varscan2
- PTPN13 | c.4250G>A p.R1417H (on ENST00000411767 / NM_080683.3; = p.R1398H on NM_006264.3) | Missense Mutation (SNP) | VAF 50/194 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs528674242, COSV57408559; called by muse, mutect2, varscan2
- RTL3 | c.56G>A p.R19Q | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.025); catalogued as rs892209848; called by muse, mutect2, varscan2
- RYR2 | c.11410G>A p.D3804N | Missense Mutation (SNP) | VAF 94/141 reads (67%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.982); catalogued as rs1260070394; called by muse, mutect2, varscan2
- SMC2 | c.2680G>T p.A894S | Missense Mutation (SNP) | VAF 20/141 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.014); catalogued as rs1564109280; called by muse, mutect2, varscan2
- SYNE1 | c.23137C>T p.R7713C (on ENST00000367255 / NM_182961.4; = p.R7642C on NM_033071.3) | Missense Mutation (SNP) | VAF 59/278 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as rs761198027, COSV54945602; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TSPOAP1 | c.4214G>A p.R1405Q | Missense Mutation (SNP) | VAF 176/347 reads (51%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.559); catalogued as rs372248342; called by muse, mutect2, varscan2
- TTN | c.64930G>A p.E21644K (on ENST00000591111; = p.E14220K on NM_003319.4) | Missense Mutation (SNP) | VAF 19/33 reads (58%) | PolyPhen benign (0.103); catalogued as rs376870149; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- USP29 | c.1313G>T p.C438F | Missense Mutation (SNP) | VAF 67/267 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54146716; called by muse, mutect2, varscan2
- WDFY4 | c.3946G>A p.A1316T | Missense Mutation (SNP) | VAF 76/133 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1471160454; called by muse, mutect2, varscan2
- ZNF496 | c.1313C>T p.S438L | Missense Mutation (SNP) | VAF 102/143 reads (71%) | SIFT tolerated (0.08); PolyPhen benign (0.427); catalogued as rs575724088, COSV104399369; called by muse, mutect2, varscan2
- ADAMTS17 | c.44T>C p.L15P | Missense Mutation (SNP) | VAF 123/321 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- ARMC4 | c.2934C>A p.N978K | Missense Mutation (SNP) | VAF 250/445 reads (56%) | SIFT tolerated (0.64); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- ASH1L | c.8201G>A p.R2734H (on ENST00000368346 / NM_001366177.2; = p.R2729H on NM_018489.3) | Missense Mutation (SNP) | VAF 46/240 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CCDC17 | c.551T>A p.F184Y | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- CCDC185 | c.1034G>T p.R345L | Missense Mutation (SNP) | VAF 182/257 reads (71%) | SIFT tolerated (0.29); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CCDC93 | c.1579G>A p.D527N | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHMP2B | c.255G>T p.M85I | Missense Mutation (SNP) | VAF 42/122 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CHST14 | c.832C>T p.H278Y | Missense Mutation (SNP) | VAF 176/482 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CRYBA2 | c.67del p.Q23Rfs*8 | Frame Shift Del (DEL) | VAF 37/193 reads (19%) | called by pindel, varscan2
- CSMD3 | c.5529T>A p.S1843R (on ENST00000297405 / NM_001363185.1; = p.S1739R on NM_052900.3) | Missense Mutation (SNP) | VAF 77/612 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CYBRD1 | c.689C>T p.P230L | Missense Mutation (SNP) | VAF 90/384 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- E2F1 | c.433C>T p.H145Y | Missense Mutation (SNP) | VAF 120/1172 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.067); called by muse, mutect2
- EIF2AK4 | c.2632-4T>C | Splice Region (SNP) | VAF 23/51 reads (45%) | called by muse, mutect2, varscan2
- FRMD4B | c.134C>T p.T45M | Missense Mutation (SNP) | VAF 105/161 reads (65%) | SIFT tolerated (0.06); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- GABRB3 | c.195G>A p.M65I | Missense Mutation (SNP) | VAF 90/243 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- GNAT1 | c.479C>T p.T160I | Missense Mutation (SNP) | VAF 140/484 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GRIN3B | c.1757A>G p.H586R | Missense Mutation (SNP) | VAF 186/504 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HGF | c.424A>C p.I142L | Missense Mutation (SNP) | VAF 92/459 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- HMCN1 | c.10264G>T p.D3422Y | Missense Mutation (SNP) | VAF 172/759 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HSPA4L | c.107+2_107+3dup p.X36_splice | Splice Site (INS) | VAF 15/60 reads (25%) | called by mutect2, pindel, varscan2
- IGHA2 | c.465G>C p.K155N | Missense Mutation (SNP) | VAF 135/445 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0.279); called by muse, mutect2, varscan2
- KIR2DL1 | c.1009A>G p.N337D | Missense Mutation (SNP) | VAF 277/510 reads (54%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- NPTN | c.79G>A p.A27T | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2
- OR5AP2 | c.544C>T p.H182Y | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PRAME | c.551A>T p.K184M | Missense Mutation (SNP) | VAF 11/282 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.904); called by muse, mutect2
- RELN | c.7729T>G p.F2577V | Missense Mutation (SNP) | VAF 117/281 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- RLIM | c.875G>T p.R292I | Missense Mutation (SNP) | VAF 80/98 reads (82%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- ROCK2 | c.2822_2823del p.K941Rfs*15 | Frame Shift Del (DEL) | VAF 17/96 reads (18%) | called by mutect2, pindel, varscan2
- SORT1 | c.100_139del p.Q34Cfs*10 | Frame Shift Del (DEL) | VAF 20/62 reads (32%) | called by mutect2, pindel
- SUSD4 | c.278G>A p.G93D | Missense Mutation (SNP) | VAF 68/407 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TGM2 | c.502T>C p.Y168H | Missense Mutation (SNP) | VAF 244/1112 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- UHMK1 | c.383_390delinsTG p.Q128_C130delinsL | In Frame Del (DEL) | VAF 60/543 reads (11%) | called by pindel, varscan2*
- AL031777.2 | c.336C>T p.I112= | Silent (SNP) | VAF 135/265 reads (51%) | catalogued as COSV61911980; called by muse, mutect2, varscan2
- AOPEP | c.1260C>T p.I420= | Silent (SNP) | VAF 263/620 reads (42%) | called by muse, mutect2, varscan2
- ATF7 | c.1443G>A p.S481= (on ENST00000548446 / NM_001366555.2; = p.S470= on NM_006856.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 95/291 reads (33%) | catalogued as rs372771818; called by muse, mutect2, varscan2
- AVPR2 | c.396C>A p.A132= | Silent (SNP) | VAF 345/390 reads (88%) | called by muse, mutect2, varscan2
- BRCA2 | c.6192G>A p.K2064= | Silent (SNP) | VAF 33/111 reads (30%) | catalogued as rs786202616; ClinVar: likely benign; called by muse, mutect2, varscan2
- CKAP5 | c.888A>G p.R296= | Silent (SNP) | VAF 124/244 reads (51%) | catalogued as rs1431324319; called by muse, mutect2, varscan2
- COL6A2 | c.1152G>A p.P384= | Silent (SNP) | VAF 80/232 reads (34%) | catalogued as rs148423929, COSV100154492; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- COQ9 | c.360G>A p.A120= | Silent (SNP) | VAF 162/572 reads (28%) | catalogued as rs200057404, COSV52645458, COSV99346062; called by muse, mutect2, varscan2
- DMRT3 | c.1356C>T p.T452= | Silent (SNP) | VAF 29/129 reads (22%) | catalogued as rs1418704495, COSV99505631; called by muse, mutect2, varscan2
- DPEP1 | c.951C>T p.D317= | Silent (SNP) | VAF 109/202 reads (54%) | catalogued as rs766145851; called by muse, mutect2, varscan2
- EDARADD | c.327C>T p.A109= (on ENST00000334232 / NM_145861.4; = p.A99= on NM_080738.4) | Silent (SNP) | VAF 46/209 reads (22%) | called by muse, mutect2, varscan2
- ELL | c.861G>A p.V287= | Silent (SNP) | VAF 95/206 reads (46%) | called by muse, mutect2, varscan2
- FAM170B | c.375G>A p.T125= | Silent (SNP) | VAF 115/200 reads (58%) | catalogued as rs992216383; called by muse, mutect2, varscan2
- FAM217B | c.960C>T p.S320= | Silent (SNP) | VAF 39/370 reads (11%) | catalogued as rs1466727629, COSV62564202; called by muse, mutect2, varscan2
- FKBP6 | c.12C>T p.S4= | Silent (SNP) | VAF 73/218 reads (33%) | catalogued as rs1426906046; called by muse, mutect2, varscan2
- FO393400.1 | c.510C>T p.T170= | Silent (SNP) | VAF 106/415 reads (26%) | catalogued as rs551441626, COSV54071131; called by muse, mutect2, varscan2
- HABP4 | c.1218G>A p.P406= | Silent (SNP) | VAF 146/361 reads (40%) | catalogued as rs768573343, COSV64514660, COSV64515009; called by muse, mutect2, varscan2
- HASPIN | c.1677G>T p.L559= | Silent (SNP) | VAF 28/36 reads (78%) | catalogued as COSV53993555; called by mutect2, varscan2
- HPSE2 | c.105C>T p.L35= | Silent (SNP) | VAF 75/285 reads (26%) | called by muse, mutect2, varscan2
- LGALS16 | c.282C>T p.Y94= | Silent (SNP) | VAF 80/389 reads (21%) | catalogued as rs552315094; called by muse, mutect2, varscan2
- LRRN3 | c.732C>T p.Y244= | Silent (SNP) | VAF 57/186 reads (31%) | catalogued as rs760392143, COSV57819205; called by muse, mutect2, varscan2
- MPDZ | c.1713G>A p.A571= | Silent (SNP) | VAF 34/114 reads (30%) | catalogued as rs940890746, COSV59956216; called by muse, mutect2, varscan2
- NPAP1 | c.1299T>C p.A433= | Silent (SNP) | VAF 37/129 reads (29%) | called by muse, mutect2, varscan2
- NTSR1 | c.444C>T p.R148= | Silent (SNP) | VAF 123/661 reads (19%) | catalogued as rs1185324665, COSV65139175; called by muse, varscan2
- NTSR1 | c.447C>T p.D149= | Silent (SNP) | VAF 224/656 reads (34%) | catalogued as rs1167999314, COSV100980669; called by muse, varscan2
- PCDHB13 | c.1977C>T p.H659= | Silent (SNP) | VAF 210/499 reads (42%) | catalogued as rs369930086, COSV53402352; called by muse, mutect2, varscan2
- PCDHGA8 | c.300G>A p.P100= | Silent (SNP) | VAF 81/245 reads (33%) | catalogued as COSV53900169; called by muse, mutect2, varscan2
- PRPF6 | c.1584C>T p.A528= | Silent (SNP) | VAF 173/1754 reads (10%) | catalogued as rs112093940; called by muse, mutect2, varscan2
- PSD | c.2064C>T p.G688= | Silent (SNP) | VAF 55/221 reads (25%) | catalogued as rs1386694692; called by muse, mutect2, varscan2
- RLBP1 | c.216G>A p.A72= | Silent (SNP) | VAF 92/233 reads (39%) | catalogued as COSV99175412; called by muse, mutect2, varscan2
- SEL1L2 | c.708A>G p.E236= | Silent (SNP) | VAF 34/384 reads (9%) | called by muse, mutect2
- SERPINE2 | c.102G>A p.T34= | Silent (SNP) | VAF 138/238 reads (58%) | catalogued as rs756815633, COSV51460165; called by muse, mutect2, varscan2
- SLC25A2 | c.519C>T p.L173= | Silent (SNP) | VAF 60/184 reads (33%) | called by muse, varscan2
- SLITRK5 | c.906C>A p.T302= | Silent (SNP) | VAF 120/283 reads (42%) | called by muse, mutect2, varscan2
- SPRED3 | c.687C>T p.P229= | Silent (SNP) | VAF 103/232 reads (44%) | called by muse, mutect2, varscan2
- SSC5D | c.2862C>T p.T954= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as rs556555499, COSV104432524; called by muse, mutect2
- TCAP | c.447C>T p.P149= | Silent (SNP) | VAF 113/242 reads (47%) | catalogued as rs45614332; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- TMEM132B | c.2757C>T p.C919= | Silent (SNP) | VAF 159/276 reads (58%) | catalogued as rs200940370; called by muse, mutect2, varscan2
- TPO | c.1104G>A p.P368= | Silent (SNP) | VAF 69/240 reads (29%) | catalogued as rs775265404, COSV61100258; called by muse, mutect2, varscan2
- ZFP2 | c.270T>A p.I90= | Silent (SNP) | VAF 66/227 reads (29%) | called by muse, mutect2, varscan2
- ZNF211 | c.1272C>A p.P424= (on ENST00000347302 / NM_198855.4; = p.P437= on NM_006385.5) | Silent (SNP) | VAF 62/279 reads (22%) | called by muse, mutect2, varscan2
- AC093155.3 | c.767-903G>A | Intron (SNP) | VAF 57/137 reads (42%) | catalogued as COSV100777677; called by muse, mutect2, varscan2
- ACSF3 | c.*146G>A | 3'UTR (SNP) | VAF 147/519 reads (28%) | called by muse, mutect2, varscan2
- AL132655.6 | chr20:58840622 C>T | 5'Flank (SNP) | VAF 30/259 reads (12%) | catalogued as rs953102685, COSV100006175; called by muse, mutect2, varscan2
- ARF5 | c.-63C>T | 5'UTR (SNP) | VAF 16/35 reads (46%) | catalogued as rs959312698; called by muse, mutect2, varscan2
- ATG16L2 | c.825-467C>T | Intron (SNP) | VAF 17/26 reads (65%) | catalogued as rs1260170162; called by muse, mutect2, varscan2
- DUSP13 | c.*686C>T | 3'UTR (SNP) | VAF 46/186 reads (25%) | called by muse, mutect2, varscan2
- GAP43 | c.31-12130T>C | Intron (SNP) | VAF 56/233 reads (24%) | catalogued as rs373081251; called by muse, mutect2, varscan2
- HYPK | c.-92G>C | 5'UTR (SNP) | VAF 68/196 reads (35%) | called by muse, mutect2, varscan2
- HYPK | c.-91G>T | 5'UTR (SNP) | VAF 71/199 reads (36%) | called by muse, mutect2, varscan2
- LY6G5C | c.346-899G>A | Intron (SNP) | VAF 32/134 reads (24%) | called by muse, mutect2, varscan2
- NBR2 | n.340T>C | RNA (SNP) | VAF 385/838 reads (46%) | catalogued as rs561096358; called by muse, mutect2, varscan2
- NLGN4Y | c.*1286G>A | 3'UTR (SNP) | VAF 87/293 reads (30%) | called by muse, mutect2, varscan2
- OR11H6 | chr14:20229641 C>T | 3'Flank (SNP) | VAF 43/142 reads (30%) | called by muse, mutect2, varscan2
- PDE7B | c.711+118C>T | Intron (SNP) | VAF 46/174 reads (26%) | catalogued as rs750908439, COSV100367475; called by muse, mutect2
- STRA6 | c.267-42G>T | Intron (SNP) | VAF 63/169 reads (37%) | called by muse, mutect2, varscan2
- ZNF578 | chr19:52451350 C>T | 5'Flank (SNP) | VAF 83/302 reads (27%) | called by muse, mutect2, varscan2
